Gene-level copy-number profile of tumor specimen TCGA-25-1632-01A from TCGA case TCGA-25-1632, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.4 years (24,993 days).
Specimen TCGA-25-1632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2ba3a197-86fc-466a-a9be-54e24daba3a4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1632-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/149e880b-5ca5-4c9d-b752-623888a7830b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 815; copy number 2: 11,717; copy number 3: 14,389; copy number 4: 26,769; copy number 5: 4,482; copy number 6: 668; copy number 7: 622; copy number 8: 218; copy number 9: 72; copy number 11: 51; copy number 14: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1632-01): tumor purity 0.97, ploidy 3.57, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 133 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:61,561,569–62,297,609, 1 gene, copy number 11 (within-gene range 4–11): PTPRG.
- chr3:62,118,300–66,038,834, 50 genes, copy number 11: RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040, MAGI1, AC121493.1, ILF2P1, RPL17P17, MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1.
- chr5:14,143,342–14,871,778, 10 genes, copy number 14 (within-gene range 8–14): TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2.
- chr8:8,783,354–9,782,346, 24 genes, copy number 9 (within-gene range 6–9): MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3, TNKS, AC103834.1.
- chr8:19,404,161–20,372,769, 13 genes, copy number 9 (within-gene range 6–9): CSGALNACT1, AC090541.1, INTS10, LPL, AC100802.1, RPL30P9, SLC18A1, ATP6V1B2, RNU6-892P, LZTS1, LZTS1-AS1, RNA5SP257, AC023403.1.
- chr8:23,190,452–23,296,279, 6 genes, copy number 9 (within-gene range 3–9): TNFRSF10A, RPL23AP55, AC100861.1, AC100861.2, CHMP7, R3HCC1.
- chr8:25,179,113–25,507,911, 8 genes, copy number 9: AC041005.1, DOCK5, AC091185.2, MIR6876, GNRH1, AC091185.1, KCTD9, CDCA2.
- chr8:119,325,171–120,445,402, 20 genes, copy number 9: MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13.
- chr8:121,380,137–121,380,465, 1 gene, copy number 9: RPL35AP19.

Autosomal genes at a single copy (total copy number 1): 815. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
